TCGA case TCGA-74-6584 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Swedish Neurosciences. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/22b5cbba-cc78-4377-a08c-a9413294c3bf

Demographics
Sex at birth: female; Age at index: 55 years; Vital status: Alive.

Diagnoses (3)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 55.4 years (20,232 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 65 days; Treatment dose: 5,760 cGy; Course number: 1; Number of fractions: 32; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 65 days; Number of cycles: 1; Treatment dose: 6,750 mg; Prescribed dose: 150; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 95 days; Days to treatment end: 95 days; Treatment dose: 1,000 cGy; Course number: 2; Number of fractions: 1; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 98 days; Number of cycles: 11; Treatment dose: 110 mg/m2; Treatment outcome: Treatment Ongoing; Prescribed dose: 10; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 99 days; Number of cycles: 5; Treatment dose: 12,600 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 120; Prescribed dose units: mg/day; Route of administration: Oral.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 55.6 years (20,323 days); Days to diagnosis: 91 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
3. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 55.6 years (20,323 days); Days to diagnosis: 91 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (4 entries)
- Day 91 (post initial treatment): Progression or recurrence: Yes; Days to progression: 91 days.
- Days to follow up: 228 days; Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Preoperative.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-74-6584-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.7.
  Slide TCGA-74-6584-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-74-6584-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Avastin.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Follow-up form 1: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 228 days; disease-specific survival: no event (censored), 228 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 91 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-74-6584-01A-11D-1842-01): tumor purity 0.53, ploidy 4.09, whole-genome doublings 1.
